Somatic mutation profile of cancer-model specimen HCM-CSHL-0838-C18-85M (3D Organoid, passage 3; aliquot HCM-CSHL-0838-C18-85M-01D-A85L-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0838-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 58.6 years (21,407 days).
Specimen HCM-CSHL-0838-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 3.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5fd0acc-d721-4060-a960-1f6f47c389a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0838-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0838-C18-10A-01D-A85L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4f040c7-4376-49eb-a7ed-902cc4b3ca90

The open-access MAF lists 228 somatic variants for this specimen: 171 protein-altering or splice-affecting, 50 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 151, Silent 50, Nonsense Mutation 5, Intron 5, Frame Shift Del 4, Splice Region 4, Splice Site 3, In Frame Del 2, Frame Shift Ins 1, 3'UTR 1, In Frame Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1745C>T p.S582L (on ENST00000281708 / NM_001349798.2; = p.S502L on NM_018315.5) | Missense Mutation (SNP) | VAF 131/131 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV104381731, COSV55890836; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 290/290 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.2240C>T p.A747V | Missense Mutation (SNP) | VAF 215/425 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs372679186; called by muse, mutect2, varscan2
- ADAMTS12 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 235/377 reads (62%) | SIFT tolerated (0.77); PolyPhen benign (0.014); catalogued as rs1475880471; called by muse, mutect2, varscan2
- BEST3 | c.1955A>C p.K652T | Missense Mutation (SNP) | VAF 250/338 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.287); catalogued as COSV100437572; called by muse, mutect2, varscan2
- BTAF1 | c.3703C>T p.Q1235* | Nonsense Mutation (SNP) | VAF 120/270 reads (44%) | catalogued as COSV56437564; called by muse, mutect2, varscan2
- CAPRIN2 | c.1062G>A p.E354= | Splice Region (SNP) | VAF 184/292 reads (63%) | catalogued as rs753169505; called by muse, varscan2
- CASZ1 | c.4969_5004del p.P1657_A1668del | In Frame Del (DEL) | VAF 60/210 reads (29%) | catalogued as rs762527837; called by mutect2, varscan2
- CCDC39 | c.1139T>C p.M380T | Missense Mutation (SNP) | VAF 22/419 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as rs1292687816; called by muse, mutect2
- CCNB3 | c.140A>G p.Q47R | Missense Mutation (SNP) | VAF 128/458 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs782584766; called by muse, mutect2, varscan2
- CDH11 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 174/351 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51762283; called by muse, mutect2, varscan2
- CFAP44 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 44/331 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867778503, COSV55615480; called by muse, mutect2, varscan2
- CFAP52 | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 160/160 reads (100%) | catalogued as rs369634065, COSV100235430; called by muse, mutect2, varscan2
- CSMD1 | c.4646G>C p.G1549A (on ENST00000520002; = p.G1548A on NM_033225.6) | Missense Mutation (SNP) | VAF 80/127 reads (63%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs1215820869; called by muse, mutect2, varscan2
- CSMD3 | c.5102G>T p.C1701F (on ENST00000297405 / NM_001363185.1; = p.C1597F on NM_052900.3) | Missense Mutation (SNP) | VAF 23/406 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52308972; called by muse, mutect2
- CXXC4 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 181/313 reads (58%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.992); catalogued as rs934612364; called by muse, mutect2, varscan2
- CYP19A1 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 384/798 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs761722363, COSV53057118; called by muse, mutect2, varscan2
- DISP1 | c.2870C>T p.S957L | Missense Mutation (SNP) | VAF 119/405 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.227); catalogued as rs191290309, COSV52658137; called by muse, mutect2, varscan2
- DRC1 | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 176/489 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs1472262198, COSV99717191; called by muse, mutect2, varscan2
- DYRK1A | c.2026G>T p.G676C | Missense Mutation (SNP) | VAF 33/387 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as rs148423267; called by muse, mutect2
- EDNRB | c.338G>A p.R113Q (on ENST00000377211 / NM_001201397.1; = p.R23Q on NM_000115.5) | Missense Mutation (SNP) | VAF 374/840 reads (45%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.039); catalogued as COSV100526646; called by muse, mutect2, varscan2
- ELOA | c.1996C>T p.R666W | Missense Mutation (SNP) | VAF 240/381 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV69309342; called by muse, mutect2, varscan2
- EMC10 | c.678C>T p.Y226= | Splice Region (SNP) | VAF 226/359 reads (63%) | catalogued as rs372179800; called by muse, mutect2, varscan2
- FAM47B | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 399/708 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1389383523, COSV100264435, COSV61452705; called by muse, mutect2, varscan2
- FAM47C | c.2165G>A p.R722H | Missense Mutation (SNP) | VAF 176/563 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs138293293, COSV100792387, COSV100792939; called by muse, mutect2, varscan2
- FOCAD | c.1897C>T p.L633F | Missense Mutation (SNP) | VAF 103/239 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs756840435; called by muse, mutect2, varscan2
- FUCA1 | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 101/378 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768069468; called by muse, mutect2, varscan2
- GAST | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 116/438 reads (26%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs371054978; called by muse, varscan2
- HAS1 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 473/707 reads (67%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.676); catalogued as rs747388837; called by muse, mutect2, varscan2
- HHIPL1 | c.1571A>G p.H524R | Missense Mutation (SNP) | VAF 303/479 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1406824774; called by muse, mutect2, varscan2
- HTR1A | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 160/471 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.089); catalogued as COSV60501935; called by muse, mutect2, varscan2
- HYDIN | c.11495G>A p.R3832H | Missense Mutation (SNP) | VAF 121/215 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs7198721; called by muse, mutect2, varscan2
- KCTD16 | c.690C>G p.F230L | Missense Mutation (SNP) | VAF 155/466 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV72578208; called by muse, mutect2, varscan2
- KDM6A | c.2971G>A p.E991K | Missense Mutation (SNP) | VAF 182/363 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV65041880; called by muse, mutect2, varscan2
- KMT5B | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 247/468 reads (53%) | catalogued as COSV100069992, COSV58568821; called by muse, mutect2, varscan2
- LAMA3 | c.9560G>A p.R3187H (on ENST00000313654 / NM_198129.4; = p.R1578H on NM_000227.6) | Missense Mutation (SNP) | VAF 131/260 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs143170913; called by muse, mutect2, varscan2
- MORC1 | c.2328G>T p.L776F | Missense Mutation (SNP) | VAF 190/302 reads (63%) | SIFT tolerated (0.24); PolyPhen benign (0.367); catalogued as rs1296771765; called by mutect2, varscan2
- NBEAL2 | c.6179G>A p.R2060H | Missense Mutation (SNP) | VAF 225/393 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as rs764406411; called by muse, mutect2, varscan2
- NLRP8 | c.2365C>T p.R789C | Missense Mutation (SNP) | VAF 87/288 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs547425685; called by muse, mutect2, varscan2
- OBSCN | c.3109C>T p.R1037W | Missense Mutation (SNP) | VAF 353/549 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs202144178; called by muse, mutect2, varscan2
- PA2G4 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 149/489 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.342); catalogued as rs1468032069; called by muse, mutect2, varscan2
- PCDHA4 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 200/636 reads (31%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as rs13189658, COSV63539039; called by muse, mutect2, varscan2
- PCDHA5 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 401/591 reads (68%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.869); catalogued as rs1554128404, COSV65350329; called by muse, mutect2, varscan2
- PRKD1 | c.1909C>T p.L637F | Missense Mutation (SNP) | VAF 81/256 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761962478; called by muse, mutect2, varscan2
- PRR23C | c.335C>T p.S112L | Missense Mutation (SNP) | VAF 261/706 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1200375371; called by muse, mutect2, varscan2
- PTPRO | c.509-1G>T p.X170_splice | Splice Site (SNP) | VAF 128/190 reads (67%) | catalogued as COSV55502459; called by muse, mutect2, varscan2
- RIMS3 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 126/454 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV65503872, COSV65504931; called by muse, mutect2, varscan2
- RPL17-C18orf32 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 214/216 reads (99%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as rs1255028692; called by muse, mutect2, varscan2
- SLC35E1 | c.352G>T p.G118C | Missense Mutation (SNP) | VAF 335/472 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1258822687; called by muse, mutect2, varscan2
- SULF2 | c.1967G>A p.R656Q | Missense Mutation (SNP) | VAF 359/508 reads (71%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs767855983; called by muse, mutect2, varscan2
- SYMPK | c.3742G>A p.A1248T | Missense Mutation (SNP) | VAF 45/630 reads (7%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs1460950394; called by muse, mutect2
- SYNE1 | c.10978G>T p.A3660S (on ENST00000367255 / NM_182961.4; = p.A3645S on NM_033071.3) | Missense Mutation (SNP) | VAF 169/489 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV55021144; called by muse, mutect2, varscan2
- TRDN | c.143C>A p.A48E | Missense Mutation (SNP) | VAF 183/455 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1278830566; called by muse, mutect2, varscan2
- TRIM24 | c.3115C>T p.R1039C (on ENST00000343526 / NM_015905.3; = p.R1005C on NM_003852.4) | Missense Mutation (SNP) | VAF 138/444 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1166324119, COSV58978097; called by muse, mutect2, varscan2
- TTYH1 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 127/588 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as rs1325981551, COSV56611995; called by muse, mutect2, varscan2
- USP19 | c.1225C>A p.P409T | Missense Mutation (SNP) | VAF 152/388 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1242657943; called by muse, mutect2, varscan2
- WIZ | c.5132G>A p.R1711H (on ENST00000673675 / NM_001371589.1; = p.R616H on NM_021241.3) | Missense Mutation (SNP) | VAF 41/884 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs770421567; called by muse, mutect2
- ZFYVE9 | c.3397C>T p.R1133W | Missense Mutation (SNP) | VAF 156/262 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs760825781, COSV55095322; called by muse, mutect2, varscan2
- ZNF814 | c.1603C>G p.L535V | Missense Mutation (SNP) | VAF 183/535 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV101457231; called by muse, mutect2, varscan2
- ZNF835 | c.1513C>T p.P505S | Missense Mutation (SNP) | VAF 328/495 reads (66%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV101606417; called by muse, mutect2, varscan2
- A1BG | c.355_359delinsACC p.P119Tfs*38 | Frame Shift Del (DEL) | VAF 44/369 reads (12%) | called by pindel, varscan2*
- ABCC12 | c.278T>G p.F93C | Missense Mutation (SNP) | VAF 130/229 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ACADL | c.191T>A p.V64E | Missense Mutation (SNP) | VAF 77/277 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- ADAMTS20 | c.2459T>C p.L820S | Missense Mutation (SNP) | VAF 63/209 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ADPRHL1 | c.2849C>T p.T950I | Missense Mutation (SNP) | VAF 33/854 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.362); called by muse, mutect2
- ALYREF | c.335G>A p.G112D | Missense Mutation (SNP) | VAF 149/630 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ANKRD55 | c.1423A>C p.S475R | Missense Mutation (SNP) | VAF 179/513 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANO5 | c.2664G>T p.L888F | Missense Mutation (SNP) | VAF 78/384 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- APC | c.3516_3522dup p.Q1175Cfs*6 | Frame Shift Ins (INS) | VAF 182/325 reads (56%) | called by mutect2, varscan2
- APC | c.4260del p.S1421Vfs*52 | Frame Shift Del (DEL) | VAF 92/395 reads (23%) | called by mutect2, pindel, varscan2
- ARHGAP31 | c.2998G>A p.D1000N | Missense Mutation (SNP) | VAF 20/603 reads (3%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.265); called by muse, mutect2
- ARHGEF18 | c.2156G>T p.S719I (on ENST00000359920 / NM_001130955.2; = p.S615I on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 157/437 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- B3GNT3 | c.389G>T p.W130L | Missense Mutation (SNP) | VAF 174/530 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BPIFB6 | c.982G>C p.G328R | Missense Mutation (SNP) | VAF 113/654 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- BRWD1 | c.4382G>A p.R1461K | Missense Mutation (SNP) | VAF 97/192 reads (51%) | SIFT tolerated (0.55); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CACNA2D1 | c.2693A>G p.Y898C (on ENST00000356253 / NM_001366867.1; = p.Y886C on NM_000722.4) | Missense Mutation (SNP) | VAF 222/468 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- CATSPER4 | c.153G>C p.E51D | Missense Mutation (SNP) | VAF 149/455 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC166 | c.740A>C p.Q247P | Missense Mutation (SNP) | VAF 237/1340 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- CCDC183 | c.1497G>C p.Q499H | Missense Mutation (SNP) | VAF 162/162 reads (100%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- CCT6A | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 72/423 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- CD177 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 145/703 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- CDK16 | c.1187A>T p.K396M | Missense Mutation (SNP) | VAF 35/705 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2
- CELSR1 | c.3695C>T p.A1232V | Missense Mutation (SNP) | VAF 111/523 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CEMIP | c.1235C>A p.T412K | Missense Mutation (SNP) | VAF 29/585 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- CFTR | c.65C>G p.P22R | Missense Mutation (SNP) | VAF 71/383 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHRDL1 | c.425C>G p.S142W (on ENST00000372045; = p.S148W on NM_145234.4) | Missense Mutation (SNP) | VAF 30/494 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2
- CPOX | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 143/764 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSMD1 | c.583T>C p.W195R | Missense Mutation (SNP) | VAF 81/81 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CUX2 | c.719G>A p.G240D | Missense Mutation (SNP) | VAF 109/335 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DALRD3 | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 245/418 reads (59%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DBX2 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 178/568 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- DNAH17 | c.8358T>G p.I2786M | Missense Mutation (SNP) | VAF 169/518 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- DNAH9 | c.1787G>A p.G596E | Missense Mutation (SNP) | VAF 199/199 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- DRD3 | c.1025G>T p.W342L | Missense Mutation (SNP) | VAF 86/252 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSEL | c.3128C>A p.P1043H | Missense Mutation (SNP) | VAF 28/439 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EIF4G3 | c.200G>A p.C67Y | Missense Mutation (SNP) | VAF 77/234 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- EXD3 | c.1307C>A p.P436Q | Missense Mutation (SNP) | VAF 193/402 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- FABP7 | c.351C>T p.T117= | Splice Region (SNP) | VAF 94/336 reads (28%) | called by muse, mutect2, varscan2
- FAM122A | c.233T>C p.V78A | Missense Mutation (SNP) | VAF 357/357 reads (100%) | SIFT tolerated (0.48); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- FAM83H | c.2546A>C p.D849A | Missense Mutation (SNP) | VAF 46/1340 reads (3%) | SIFT tolerated (0.56); PolyPhen benign (0.039); called by muse, mutect2
- FANCL | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 73/297 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- FLNA | c.5399A>T p.K1800M (on ENST00000369850 / NM_001110556.2; = p.K1792M on NM_001456.3) | Missense Mutation (SNP) | VAF 231/592 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- FNDC1 | c.4319T>A p.I1440N | Missense Mutation (SNP) | VAF 196/620 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- GOLGA8H | c.791G>A p.C264Y | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GPR156 | c.587G>C p.S196T | Missense Mutation (SNP) | VAF 112/365 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- GZMA | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 70/294 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- HS3ST2 | c.694T>G p.S232A | Missense Mutation (SNP) | VAF 176/419 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HUWE1 | c.1957+1G>A p.X653_splice | Splice Site (SNP) | VAF 69/289 reads (24%) | called by muse, mutect2, varscan2
- HYDIN | c.9326T>C p.L3109P | Missense Mutation (SNP) | VAF 126/275 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- IFT52 | c.866C>A p.T289N | Missense Mutation (SNP) | VAF 149/797 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- IL12RB2 | c.88A>T p.R30* | Nonsense Mutation (SNP) | VAF 20/317 reads (6%) | called by muse, mutect2
- KLHL34 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 260/688 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- L1CAM | c.636C>A p.H212Q | Missense Mutation (SNP) | VAF 30/710 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.205); called by muse, mutect2
- LAS1L | c.1828C>A p.P610T | Missense Mutation (SNP) | VAF 287/670 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- LCT | c.1807T>C p.S603P | Missense Mutation (SNP) | VAF 44/656 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- LRRK2 | c.6161C>T p.A2054V | Missense Mutation (SNP) | VAF 208/335 reads (62%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- LSS | c.587G>C p.W196S | Missense Mutation (SNP) | VAF 11/385 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAGEC1 | c.1951C>T p.P651S | Missense Mutation (SNP) | VAF 147/645 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAP2 | c.3082G>T p.V1028L | Missense Mutation (SNP) | VAF 19/385 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.138); called by muse, mutect2
- MED17 | c.638-1G>T p.X213_splice | Splice Site (SNP) | VAF 30/193 reads (16%) | called by muse, mutect2, varscan2
- MFSD14A | c.590T>A p.I197K | Missense Mutation (SNP) | VAF 26/500 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- MTA1 | c.876G>T p.E292D | Missense Mutation (SNP) | VAF 102/446 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- MTARC1 | c.948G>T p.Q316H | Missense Mutation (SNP) | VAF 107/376 reads (28%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- NEFM | c.1357G>A p.V453I | Missense Mutation (SNP) | VAF 168/168 reads (100%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- NKX2-4 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 178/969 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.058); called by muse, varscan2
- NLRP13 | c.1507A>G p.T503A | Missense Mutation (SNP) | VAF 146/504 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.022); called by muse, mutect2
- NONO | c.1071_1094del p.E361_E368del | In Frame Del (DEL) | VAF 206/246 reads (84%) | called by mutect2, varscan2
- NUP188 | c.827G>A p.G276D | Missense Mutation (SNP) | VAF 124/237 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUP188 | c.3033A>C p.E1011D | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- OPHN1 | c.1374A>T p.E458D | Missense Mutation (SNP) | VAF 87/408 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- P2RX3 | c.836A>C p.N279T | Missense Mutation (SNP) | VAF 81/451 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB11 | c.2294A>C p.K765T | Missense Mutation (SNP) | VAF 234/386 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- PDE4A | c.995T>C p.M332T (on ENST00000380702 / NM_001111307.2; = p.M93T on NM_006202.3) | Missense Mutation (SNP) | VAF 22/400 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.342); called by muse, mutect2
- PGLYRP2 | c.259A>C p.S87R | Missense Mutation (SNP) | VAF 173/530 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- PHIP | c.5429T>G p.L1810W | Missense Mutation (SNP) | VAF 84/294 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PLEKHG4B | c.1048G>A p.E350K (on ENST00000283426; = p.E706K on NM_052909.5) | Missense Mutation (SNP) | VAF 93/308 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PPP2R5A | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 79/456 reads (17%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRND | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 185/957 reads (19%) | called by muse, mutect2, varscan2
- RAD54B | c.624del p.Q209Sfs*78 | Frame Shift Del (DEL) | VAF 682/950 reads (72%) | called by mutect2, pindel, varscan2
- RBBP6 | c.5272G>A p.E1758K | Missense Mutation (SNP) | VAF 131/254 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- RBM25 | c.1564T>A p.L522M | Missense Mutation (SNP) | VAF 72/266 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- RUFY4 | c.801G>C p.E267D | Missense Mutation (SNP) | VAF 144/551 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- SCP2D1 | c.441A>C p.E147D | Missense Mutation (SNP) | VAF 88/522 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SFRP1 | c.394C>T p.L132F | Missense Mutation (SNP) | VAF 111/652 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- SLC25A46 | c.862C>G p.L288V | Missense Mutation (SNP) | VAF 90/381 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SNX9 | c.256A>G p.S86G | Missense Mutation (SNP) | VAF 177/481 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SPANXD | c.184A>T p.T62S | Missense Mutation (SNP) | VAF 61/736 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.012); called by muse, mutect2
- SRF | c.1469A>C p.N490T | Missense Mutation (SNP) | VAF 131/534 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- TAB3 | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 223/568 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TCAF1 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 267/697 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEAD3 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 14/464 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.363); called by muse, mutect2
- TESK1 | c.1727T>G p.F576C | Missense Mutation (SNP) | VAF 144/440 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- TLR7 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 38/524 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- TLR8 | c.1438G>T p.A480S (on ENST00000218032 / NM_138636.5; = p.A498S on NM_016610.4) | Missense Mutation (SNP) | VAF 120/521 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- TM9SF4 | c.1613T>A p.F538Y | Missense Mutation (SNP) | VAF 106/771 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- TMEM115 | c.107T>G p.L36R | Missense Mutation (SNP) | VAF 174/395 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- TMTC1 | c.740G>T p.G247V (on ENST00000539277 / NM_001193451.2; = p.G139V on NM_175861.3) | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.743); called by muse, mutect2
- TRPC7 | c.1110G>C p.W370C | Missense Mutation (SNP) | VAF 64/366 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TTN | c.79002G>T p.K26334N (on ENST00000591111; = p.K18910N on NM_003319.4) | Missense Mutation (SNP) | VAF 16/504 reads (3%) | PolyPhen possibly damaging (0.55); called by muse, mutect2
- TUBD1 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 240/502 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBE3C | c.2933C>A p.S978Y | Missense Mutation (SNP) | VAF 189/451 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- USP15 | c.1306_1314dup p.D436_F438dup (on ENST00000280377 / NM_001351159.2; = p.D407_F409dup on NM_006313.3 and 5 other RefSeq transcripts) | In Frame Ins (INS) | VAF 42/260 reads (16%) | called by mutect2, varscan2
- USP34 | c.8881C>G p.L2961V | Missense Mutation (SNP) | VAF 50/326 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- USP4 | c.554A>T p.N185I | Missense Mutation (SNP) | VAF 171/370 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- USP9X | c.1317A>G p.A439= | Splice Region (SNP) | VAF 63/305 reads (21%) | called by muse, mutect2, varscan2
- UXT | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 211/490 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- WNK3 | c.5389C>T p.P1797S | Missense Mutation (SNP) | VAF 100/422 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ZNF124 | c.781C>A p.P261T (on ENST00000543802 / NM_001297568.1; = p.P199T on NM_003431.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 150/487 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZNF273 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 163/371 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ZNF765 | c.348C>G p.I116M | Missense Mutation (SNP) | VAF 70/305 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ZNF829 | c.747del p.F249Lfs*39 | Frame Shift Del (DEL) | VAF 290/576 reads (50%) | called by mutect2, pindel, varscan2
- AP1B1 | c.519C>T p.N173= | Silent (SNP) | VAF 150/257 reads (58%) | called by muse, mutect2, varscan2
- ARL15 | c.132C>A p.G44= | Silent (SNP) | VAF 121/367 reads (33%) | catalogued as rs943012169; called by muse, mutect2, varscan2
- CASZ1 | c.987C>T p.N329= | Silent (SNP) | VAF 139/579 reads (24%) | catalogued as rs377360245, COSV59735740; called by muse, mutect2, varscan2
- CEACAM3 | c.321G>T p.L107= | Silent (SNP) | VAF 101/388 reads (26%) | called by muse, mutect2, varscan2
- CFAP43 | c.3636G>A p.V1212= | Silent (SNP) | VAF 181/181 reads (100%) | called by muse, mutect2, varscan2
- CLINT1 | c.261T>G p.A87= | Silent (SNP) | VAF 13/290 reads (4%) | called by muse, mutect2
- CPOX | c.327G>A p.R109= | Silent (SNP) | VAF 144/765 reads (19%) | called by muse, mutect2, varscan2
- DCAF1 | c.45T>A p.T15= | Silent (SNP) | VAF 163/328 reads (50%) | called by muse, mutect2, varscan2
- DEPDC1B | c.951T>C p.L317= | Silent (SNP) | VAF 12/400 reads (3%) | called by muse, mutect2
- DIAPH3 | c.2919C>T p.N973= (on ENST00000400324 / NM_001042517.2; = p.N710= on NM_030932.3) | Silent (SNP) | VAF 179/443 reads (40%) | called by muse, mutect2, varscan2
- DMRTB1 | c.318C>T p.D106= | Silent (SNP) | VAF 201/646 reads (31%) | called by muse, mutect2, varscan2
- DNAH5 | c.7482G>A p.A2494= | Silent (SNP) | VAF 478/717 reads (67%) | called by muse, mutect2, varscan2
- F8 | c.4371C>A p.A1457= | Silent (SNP) | VAF 133/510 reads (26%) | catalogued as rs1557278434; called by muse, mutect2, varscan2
- FAT3 | c.4083C>T p.T1361= | Silent (SNP) | VAF 239/520 reads (46%) | called by muse, mutect2, varscan2
- FMN2 | c.198C>T p.S66= | Silent (SNP) | VAF 113/491 reads (23%) | called by muse, mutect2, varscan2
- FOXI2 | c.831G>A p.P277= | Silent (SNP) | VAF 422/422 reads (100%) | catalogued as rs977042029; called by muse, varscan2
- GOLGA8H | c.792C>T p.C264= | Silent (SNP) | VAF 13/170 reads (8%) | called by muse, mutect2, varscan2
- GPC4 | c.660T>G p.T220= | Silent (SNP) | VAF 153/669 reads (23%) | called by muse, mutect2, varscan2
- HELZ2 | c.357G>A p.T119= | Silent (SNP) | VAF 167/799 reads (21%) | catalogued as rs199551749, COSV100915479; called by muse, varscan2
- HTT | c.2352C>T p.R784= | Silent (SNP) | VAF 141/371 reads (38%) | catalogued as rs748426062; called by muse, mutect2, varscan2
- JPH4 | c.852C>T p.G284= | Silent (SNP) | VAF 205/622 reads (33%) | catalogued as COSV62509741; called by muse, mutect2, varscan2
- KCNH8 | c.2691C>T p.N897= | Silent (SNP) | VAF 190/400 reads (48%) | catalogued as rs751554750; called by muse, mutect2
- KIAA1210 | c.1773G>A p.K591= | Silent (SNP) | VAF 170/680 reads (25%) | called by muse, mutect2, varscan2
- KRT1 | c.519C>T p.I173= | Silent (SNP) | VAF 287/399 reads (72%) | called by muse, mutect2, varscan2
- LRP1 | c.5505C>T p.V1835= | Silent (SNP) | VAF 324/483 reads (67%) | called by muse, mutect2, varscan2
- MTMR1 | c.1974C>T p.A658= | Silent (SNP) | VAF 25/645 reads (4%) | called by muse, mutect2
- NR3C2 | c.2223C>T p.V741= | Silent (SNP) | VAF 28/378 reads (7%) | called by muse, mutect2
- OBSCN | c.10329C>G p.L3443= | Silent (SNP) | VAF 11/308 reads (4%) | called by muse, mutect2
- PAPPA2 | c.2493C>T p.D831= | Silent (SNP) | VAF 188/577 reads (33%) | called by muse, mutect2, varscan2
- PBRM1 | c.5043C>T p.R1681= (on ENST00000296302 / NM_001366071.2; = p.R1574= on NM_018313.5) | Silent (SNP) | VAF 125/307 reads (41%) | called by muse, mutect2, varscan2
- PCDHB13 | c.1782C>T p.G594= | Silent (SNP) | VAF 91/775 reads (12%) | catalogued as rs200857606; called by muse, mutect2, varscan2
- POLD4 | c.153G>A p.Q51= | Silent (SNP) | VAF 176/783 reads (22%) | catalogued as rs145225786; called by muse, mutect2, varscan2
- PRSS36 | c.978G>A p.G326= | Silent (SNP) | VAF 144/316 reads (46%) | called by muse, mutect2, varscan2
- RCC1L | c.891C>T p.A297= | Silent (SNP) | VAF 49/774 reads (6%) | catalogued as rs1356900075; called by muse, mutect2
- SALL3 | c.3666G>T p.G1222= | Silent (SNP) | VAF 33/611 reads (5%) | called by muse, mutect2
- SDK1 | c.6552G>A p.P2184= | Silent (SNP) | VAF 450/878 reads (51%) | catalogued as rs764760882, COSV67389853; called by muse, mutect2, varscan2
- SEC63 | c.1890C>A p.T630= | Silent (SNP) | VAF 31/386 reads (8%) | called by muse, mutect2
- SH3D19 | c.1101C>T p.S367= | Silent (SNP) | VAF 176/285 reads (62%) | called by muse, mutect2, varscan2
- SHISA2 | c.264C>T p.C88= | Silent (SNP) | VAF 180/842 reads (21%) | called by muse, mutect2, varscan2
- SI | c.5235T>C p.F1745= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as COSV52303453; called by muse, mutect2, varscan2
- SI | c.3990T>C p.C1330= | Silent (SNP) | VAF 170/295 reads (58%) | called by muse, mutect2, varscan2
- SLC35F2 | c.9A>C p.A3= | Silent (SNP) | VAF 228/496 reads (46%) | catalogued as rs371255646; called by muse, mutect2, varscan2
- SLFN13 | c.396T>G p.S132= | Silent (SNP) | VAF 115/421 reads (27%) | called by muse, mutect2, varscan2
- TBXA2R | c.837C>T p.A279= | Silent (SNP) | VAF 144/440 reads (33%) | catalogued as rs758529770; called by muse, mutect2, varscan2
- TGM1 | c.642C>T p.N214= | Silent (SNP) | VAF 326/480 reads (68%) | catalogued as rs761501855; ClinVar: likely benign; called by muse, mutect2, varscan2
- TRIO | c.7422C>T p.P2474= | Silent (SNP) | VAF 485/729 reads (67%) | catalogued as rs772235342; called by muse, mutect2, varscan2
- USP27X | c.1128G>A p.L376= | Silent (SNP) | VAF 26/676 reads (4%) | called by muse, mutect2
- VWA3A | c.1143A>C p.P381= | Silent (SNP) | VAF 19/343 reads (6%) | called by muse, mutect2
- WHRN | c.150G>C p.L50= | Silent (SNP) | VAF 153/449 reads (34%) | called by muse, mutect2, varscan2
- ZNF850 | c.886C>T p.L296= | Silent (SNP) | VAF 165/469 reads (35%) | called by muse, mutect2, varscan2
- AGK | c.141+166C>A | Intron (SNP) | VAF 109/541 reads (20%) | called by muse, mutect2, varscan2
- AL627230.3 | c.76-25C>A | Intron (SNP) | VAF 82/530 reads (15%) | called by muse, mutect2
- MRPL21 | c.553+110G>A | Intron (SNP) | VAF 419/826 reads (51%) | called by muse, varscan2
- NAXD | chr13:110615619 C>G | 5'Flank (SNP) | VAF 206/916 reads (22%) | called by muse, mutect2, varscan2
- PEG10 | c.*334C>T | 3'UTR (SNP) | VAF 112/499 reads (22%) | called by muse, mutect2, varscan2
- RBM44 | c.-98-2478C>A | Intron (SNP) | VAF 162/406 reads (40%) | called by muse, mutect2, varscan2
- VAPA | c.418-5402C>T | Intron (SNP) | VAF 117/287 reads (41%) | called by muse, mutect2, varscan2
